Somatic mutation profile of tumor specimen C3L-08791-01 (aliquot CPT0496840006) from CPTAC case C3L-08791, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 54.5 years (19,924 days).
Specimen C3L-08791-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7bc3ef5-5bb8-4b06-b2de-f1c89c2d0e47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08791-31 (Blood Derived Normal), aliquot CPT0496900003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f32a2c3-e699-418f-8364-4c461a8beb12

The open-access MAF lists 157 somatic variants for this specimen: 119 protein-altering or splice-affecting, 33 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 33, Nonsense Mutation 7, Frame Shift Del 5, Intron 3, 3'UTR 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 89/271 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- APOBEC2 | c.638T>C p.L213P | Missense Mutation (SNP) | VAF 46/272 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.263); catalogued as rs1357797309; called by mutect2, varscan2
- CD22 | c.1964G>C p.G655A | Missense Mutation (SNP) | VAF 64/598 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50049765; called by mutect2, varscan2
- CHRNA4 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 62/498 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs201275400; called by mutect2, varscan2
- COL25A1 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 34/284 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs960016417, COSV67651331; called by mutect2, varscan2
- CRB1 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 68/412 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV66328752; called by mutect2, varscan2
- CSAD | c.596C>T p.A199V (on ENST00000444623 / NM_001244705.2; = p.A226V on NM_015989.5) | Missense Mutation (SNP) | VAF 46/362 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs201933521, COSV57241862; called by mutect2, varscan2
- CSMD3 | c.10843G>A p.E3615K (on ENST00000297405 / NM_001363185.1; = p.E3446K on NM_052900.3) | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); catalogued as rs745671403; called by mutect2, varscan2
- CTNND2 | c.2665C>T p.R889* | Nonsense Mutation (SNP) | VAF 60/302 reads (20%) | catalogued as COSV58884453; called by mutect2, varscan2
- CUBN | c.5376C>A p.S1792R | Missense Mutation (SNP) | VAF 45/346 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); catalogued as rs780576230; called by mutect2, varscan2
- CYFIP1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs1033163739; called by mutect2, varscan2
- DDR1 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 82/538 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs539581039; called by mutect2, varscan2
- DPP4 | c.1468G>A p.G490R | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.028); catalogued as rs772501868; called by mutect2, varscan2
- E4F1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 89/318 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs763701964; called by mutect2, varscan2
- EVC | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs932851648; called by mutect2, varscan2
- GRIN2D | c.2726C>T p.P909L | Missense Mutation (SNP) | VAF 56/299 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1335509453; called by mutect2, varscan2
- HENMT1 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 64/376 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs771530768, COSV64230874; called by mutect2, varscan2
- IDH1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 60/372 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as rs1384045653; called by mutect2, varscan2
- KIAA1755 | c.295T>G p.L99V | Missense Mutation (SNP) | VAF 52/478 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as COSV54080496, COSV54080663; called by mutect2, varscan2
- KLF8 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 54/456 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63847515; called by mutect2, varscan2
- KRTAP13-4 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV61878802; called by mutect2, varscan2
- LRP1B | c.4769A>G p.D1590G | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as rs759668695; called by mutect2, varscan2
- MAGI1 | c.776A>G p.E259G | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs1386511342; called by mutect2, varscan2
- MBD6 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 81/477 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.564); catalogued as rs150028492; called by mutect2, varscan2
- MCMBP | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 44/294 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1281322886; called by mutect2, varscan2
- MUC16 | c.4405A>G p.M1469V | Missense Mutation (SNP) | VAF 40/331 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs772740374; called by mutect2, varscan2
- MYO16 | c.3959C>G p.S1320C | Missense Mutation (SNP) | VAF 106/385 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs963117704; called by mutect2, varscan2
- NAV3 | c.3095C>A p.S1032* | Nonsense Mutation (SNP) | VAF 36/328 reads (11%) | catalogued as COSV57074522; called by mutect2, varscan2
- NCOR2 | c.325C>G p.R109G | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100656984; called by mutect2, varscan2
- NFATC1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 45/370 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs373889524, COSV53702050; called by mutect2, varscan2
- NLGN1 | c.242T>C p.L81P | Missense Mutation (SNP) | VAF 195/518 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64331439, COSV64331546, COSV64347082; called by mutect2, varscan2
- NXF3 | c.1180T>C p.F394L | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs755505803; called by mutect2, varscan2
- OXR1 | c.199G>A p.E67K (on ENST00000442977 / NM_001198532.1; = p.E66K on NM_018002.3) | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs140323560, COSV71537877; called by mutect2, varscan2
- PAPPA2 | c.3101C>A p.A1034E | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV62801216; called by mutect2, varscan2
- PCDH19 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 86/467 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55257726; called by mutect2, varscan2
- PCDHB12 | c.430G>C p.E144Q | Missense Mutation (SNP) | VAF 58/350 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99506626; called by mutect2, varscan2
- PCDHB14 | c.1153A>G p.I385V | Missense Mutation (SNP) | VAF 36/320 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.246); catalogued as rs1262659303; called by mutect2, varscan2
- PCNT | c.7204G>A p.E2402K | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779669784; called by mutect2, varscan2
- PKHD1L1 | c.74-1G>T p.X25_splice | Splice Site (SNP) | VAF 40/184 reads (22%) | catalogued as COSV65755164; called by mutect2, varscan2
- POM121L12 | c.202T>C p.W68R | Missense Mutation (SNP) | VAF 113/448 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV68693112; called by mutect2, varscan2
- PTBP1 | c.1214G>A p.R405H (on ENST00000349038 / NM_031991.4; = p.R431H on NM_002819.5) | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV62461244; called by mutect2, varscan2
- SAP30 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.267); catalogued as rs773112767; called by mutect2, varscan2
- SLC2A8 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 72/411 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs191868016; called by mutect2, varscan2
- SLIT2 | c.1839G>T p.L613F | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56573783; called by mutect2, varscan2
- ST8SIA4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 54/290 reads (19%) | PolyPhen benign (0.208); catalogued as rs372014886; called by mutect2, varscan2
- SUPT3H | c.237A>C p.E79D (on ENST00000371460 / NM_181356.3; = p.E68D on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.662); catalogued as COSV60943659; called by mutect2, varscan2
- TFIP11 | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs143474250, COSV101316526; called by mutect2, varscan2
- TGFBR3L | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 66/360 reads (18%) | SIFT tolerated (0.19); catalogued as rs1413942129; called by mutect2, varscan2
- TMEM240 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as rs1175014443; called by mutect2, varscan2
- TMX2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); catalogued as rs1397761964; called by mutect2, varscan2
- TTN | c.54889G>A p.A18297T (on ENST00000591111; = p.A10873T on NM_003319.4) | Missense Mutation (SNP) | VAF 51/430 reads (12%) | PolyPhen probably damaging (0.915); catalogued as rs755204306, COSV60146923; ClinVar: likely benign; called by mutect2, varscan2
- WT1 | c.1430A>C p.K477T | Missense Mutation (SNP) | VAF 92/360 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60067171; called by mutect2, varscan2
- XIRP2 | c.7850A>C p.N2617T (on ENST00000628543; = p.N2792T on NM_152381.6) | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99742610; called by mutect2, varscan2
- ZFHX4 | c.3669C>G p.N1223K | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.879); catalogued as rs1366122186, COSV99257421; called by mutect2, varscan2
- ZNF208 | c.1715A>C p.K572T | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68107459; called by mutect2, varscan2
- ZNF681 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV101267391, COSV68075908; called by mutect2, varscan2
- ZNF835 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 129/384 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.278); catalogued as rs1443280493; called by mutect2, varscan2
- ABCA13 | c.3875G>T p.S1292I | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.134); called by mutect2, varscan2
- ABCA4 | c.1160G>A p.W387* | Nonsense Mutation (SNP) | VAF 46/311 reads (15%) | called by mutect2, varscan2
- ACTR1A | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 43/311 reads (14%) | called by mutect2, varscan2
- ANAPC4 | c.2405T>G p.L802R | Missense Mutation (SNP) | VAF 37/256 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); called by mutect2, varscan2
- ASXL3 | c.5924T>A p.V1975D | Missense Mutation (SNP) | VAF 57/345 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by mutect2, varscan2
- BCAM | c.1172C>G p.T391S | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by mutect2, varscan2
- CACNG7 | c.606G>C p.K202N | Missense Mutation (SNP) | VAF 57/363 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by mutect2, varscan2
- CCDC136 | c.2799G>T p.Q933H | Missense Mutation (SNP) | VAF 91/356 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- CCDC168 | c.11690A>C p.K3897T | Missense Mutation (SNP) | VAF 99/386 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.013); called by mutect2, varscan2
- CCDC168 | c.1925G>T p.C642F | Missense Mutation (SNP) | VAF 86/342 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by mutect2, varscan2
- CCDC183 | c.20C>G p.T7R | Missense Mutation (SNP) | VAF 46/390 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.069); called by mutect2, varscan2
- CDH26 | c.2416T>A p.L806M (on ENST00000348616 / NM_177980.4; = p.L139M on NM_021810.6) | Missense Mutation (SNP) | VAF 44/396 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by mutect2, varscan2
- COL6A3 | c.1679A>G p.K560R | Missense Mutation (SNP) | VAF 58/400 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.306); called by mutect2, varscan2
- DCAF12L2 | c.164T>G p.L55R | Missense Mutation (SNP) | VAF 56/375 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- DCXR | c.409C>G p.Q137E | Missense Mutation (SNP) | VAF 78/302 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by mutect2, varscan2
- DENND2C | c.2452G>T p.V818L (on ENST00000393274 / NM_001256404.2; = p.V761L on NM_198459.4) | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.657); called by mutect2, varscan2
- DISC1 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 73/548 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by mutect2, varscan2
- DYNC1H1 | c.9392A>G p.D3131G | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.253); called by mutect2, varscan2
- EFCAB2 | c.676A>T p.R226* (on ENST00000366522; = p.R90* on NM_032328.3) | Nonsense Mutation (SNP) | VAF 28/244 reads (11%) | called by mutect2, varscan2
- ENAH | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); called by mutect2, varscan2
- EVC | c.1776G>A p.Q592= | Splice Region (SNP) | VAF 27/200 reads (14%) | called by mutect2, varscan2
- EXPH5 | c.2567C>A p.T856N | Missense Mutation (SNP) | VAF 54/424 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- FCRL6 | c.798G>T p.K266N | Missense Mutation (SNP) | VAF 50/491 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.598); called by mutect2, varscan2
- FIG4 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 122/314 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.668); called by mutect2, varscan2
- FN1 | c.5965A>C p.K1989Q | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.323); called by mutect2, varscan2
- FN1 | c.3680C>T p.A1227V | Missense Mutation (SNP) | VAF 55/418 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.167); called by mutect2, varscan2
- FOSL2 | c.10del p.D4Ifs*35 | Frame Shift Del (DEL) | VAF 36/306 reads (12%) | called by mutect2, pindel, varscan2
- FSCB | c.188del p.K63Sfs*6 | Frame Shift Del (DEL) | VAF 41/373 reads (11%) | called by mutect2, pindel, varscan2
- G2E3 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 29/256 reads (11%) | called by mutect2, varscan2
- GABBR2 | c.2041G>A p.V681I | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- GABRG3 | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by mutect2, varscan2
- IKZF2 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- INSRR | c.2858A>T p.Y953F | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); called by mutect2, varscan2
- KIR2DL1 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 36/284 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.271); called by mutect2, varscan2
- L3MBTL3 | c.1777G>T p.D593Y | Missense Mutation (SNP) | VAF 80/344 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); called by mutect2, varscan2
- LAMA1 | c.776_786del p.Y259* | Frame Shift Del (DEL) | VAF 27/203 reads (13%) | called by mutect2, pindel, varscan2
- LSAMP | c.737C>A p.A246E | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0.042); called by mutect2, varscan2
- MAPK3 | c.766C>G p.H256D | Missense Mutation (SNP) | VAF 36/236 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.424); called by mutect2, varscan2
- MCF2L | c.172G>C p.E58Q (on ENST00000375608; = p.E26Q on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by mutect2, varscan2
- NECAP1 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.028); called by mutect2, varscan2
- NLGN2 | c.1180T>G p.S394A | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT tolerated (0.75); PolyPhen benign (0.003); called by mutect2, varscan2
- NOP9 | c.474del p.S159Vfs*28 | Frame Shift Del (DEL) | VAF 64/419 reads (15%) | called by pindel, varscan2
- OBSCN | c.753A>C p.E251D | Missense Mutation (SNP) | VAF 91/474 reads (19%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- OR13C3 | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by mutect2, varscan2
- OR4A47 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- OR4C11 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 43/342 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by mutect2, varscan2
- PCDH15 | c.3624G>T p.M1208I | Missense Mutation (SNP) | VAF 34/275 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.086); called by mutect2, varscan2
- PCSK7 | c.31T>A p.L11M | Missense Mutation (SNP) | VAF 52/386 reads (13%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.305); called by mutect2, varscan2
- PKD1L3 | c.2347del p.Q783Rfs*21 | Frame Shift Del (DEL) | VAF 59/432 reads (14%) | called by mutect2, pindel, varscan2
- PTPN13 | c.2597A>C p.K866T | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by mutect2, varscan2
- RFX7 | c.3128A>G p.Q1043R (on ENST00000559447 / NM_001368074.1; = p.Q1140R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/306 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by mutect2, varscan2
- RS1 | c.316C>G p.Q106E | Missense Mutation (SNP) | VAF 72/322 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- SLC16A14 | c.979T>C p.Y327H | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- TTLL5 | c.3130C>G p.Q1044E | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by mutect2, varscan2
- TXNDC17 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT tolerated (0.9); PolyPhen benign (0.006); called by mutect2, varscan2
- UHRF1BP1 | c.3458C>G p.S1153* | Nonsense Mutation (SNP) | VAF 40/321 reads (12%) | called by mutect2, varscan2
- UQCRC2 | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); called by mutect2, varscan2
- WDR19 | c.1045A>C p.K349Q | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.26); called by mutect2, varscan2
- YTHDF2 | c.1463A>C p.Q488P | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ZC2HC1A | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.043); called by mutect2, varscan2
- ZNF782 | c.1366G>C p.G456R | Missense Mutation (SNP) | VAF 66/330 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by mutect2, varscan2
- ZNF90 | c.1628G>T p.G543V | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); called by mutect2, varscan2
- ANXA13 | c.240G>A p.A80= | Silent (SNP) | VAF 78/512 reads (15%) | catalogued as rs932174402; called by mutect2, varscan2
- CAPN15 | c.666C>T p.A222= | Silent (SNP) | VAF 77/496 reads (16%) | catalogued as rs770992910, COSV54838114; called by mutect2, varscan2
- CCL4 | c.246C>G p.V82= | Silent (SNP) | VAF 116/608 reads (19%) | called by mutect2, varscan2
- CFH | c.3232A>C p.R1078= | Silent (SNP) | VAF 77/421 reads (18%) | called by mutect2, varscan2
- CNTNAP2 | c.2037C>T p.A679= | Silent (SNP) | VAF 52/415 reads (13%) | catalogued as rs539741829, COSV62276109; called by mutect2, varscan2
- DGKB | c.840C>T p.Y280= | Silent (SNP) | VAF 42/330 reads (13%) | called by mutect2, varscan2
- DYRK2 | c.66C>T p.S22= | Silent (SNP) | VAF 62/310 reads (20%) | called by mutect2, varscan2
- E2F5 | c.18C>T p.P6= | Silent (SNP) | VAF 14/131 reads (11%) | called by mutect2, varscan2
- GRM2 | c.1224C>T p.D408= | Silent (SNP) | VAF 48/293 reads (16%) | catalogued as rs758404626, COSV56586629; called by mutect2, varscan2
- HSPA6 | c.81C>A p.R27= | Silent (SNP) | VAF 9/54 reads (17%) | called by mutect2, varscan2
- IFIH1 | c.288C>T p.N96= | Silent (SNP) | VAF 43/437 reads (10%) | catalogued as rs781129531; called by mutect2, varscan2
- KCNB2 | c.804C>T p.V268= | Silent (SNP) | VAF 56/490 reads (11%) | catalogued as rs1182341056, COSV73048845; called by mutect2, varscan2
- KIAA2026 | c.2769G>A p.P923= | Silent (SNP) | VAF 36/305 reads (12%) | catalogued as rs367658582; called by mutect2, varscan2
- MPEG1 | c.219A>T p.T73= | Silent (SNP) | VAF 116/374 reads (31%) | catalogued as rs755210517; called by mutect2, varscan2
- MTHFR | c.1383G>A p.A461= | Silent (SNP) | VAF 46/344 reads (13%) | catalogued as rs199517455; called by mutect2, varscan2
- NDUFB11 | c.249C>T p.D83= | Silent (SNP) | VAF 34/320 reads (11%) | catalogued as rs192690913; called by mutect2, varscan2
- NTN1 | c.969C>T p.Y323= | Silent (SNP) | VAF 48/299 reads (16%) | called by mutect2, varscan2
- PAPPA | c.1080C>G p.L360= | Silent (SNP) | VAF 55/313 reads (18%) | called by mutect2, varscan2
- PCDH11X | c.3621G>A p.L1207= | Silent (SNP) | VAF 58/572 reads (10%) | called by mutect2, varscan2
- PCDHB12 | c.1341C>T p.N447= | Silent (SNP) | VAF 56/464 reads (12%) | catalogued as rs782291120, COSV53392904; called by mutect2, varscan2
- PLA2G7 | c.492C>A p.G164= | Silent (SNP) | VAF 61/245 reads (25%) | called by mutect2, varscan2
- POLR1G | c.552C>G p.A184= | Silent (SNP) | VAF 50/484 reads (10%) | called by mutect2, varscan2
- PTPRZ1 | c.1779T>C p.T593= | Silent (SNP) | VAF 44/424 reads (10%) | called by mutect2, varscan2
- RAB11FIP2 | c.1075C>T p.L359= | Silent (SNP) | VAF 44/358 reads (12%) | called by mutect2, varscan2
- RAVER1 | c.1572C>T p.S524= (on ENST00000615032; = p.S680= on NM_133452.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/294 reads (13%) | catalogued as rs758633927; called by mutect2, varscan2
- RIMS2 | c.1449C>G p.L483= (on ENST00000666250 / NM_001348490.2; = p.L291= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 92/574 reads (16%) | catalogued as COSV51724650, COSV99170243; called by mutect2, varscan2
- SHISA9 | c.57C>T p.R19= | Silent (SNP) | VAF 54/333 reads (16%) | called by mutect2, varscan2
- SOX4 | c.1002C>T p.P334= | Silent (SNP) | VAF 95/228 reads (42%) | catalogued as rs937217121; called by mutect2, varscan2
- SPACA3 | c.261C>G p.A87= | Silent (SNP) | VAF 58/450 reads (13%) | called by mutect2, varscan2
- TTN | c.75342C>T p.F25114= (on ENST00000591111; = p.F17690= on NM_003319.4) | Silent (SNP) | VAF 42/302 reads (14%) | called by mutect2, varscan2
- YJU2 | c.909C>T p.G303= | Silent (SNP) | VAF 48/300 reads (16%) | catalogued as rs767728648, COSV53606160; called by mutect2, varscan2
- ZCCHC14 | c.669C>G p.T223= (on ENST00000268616; = p.T360= on NM_015144.3) | Silent (SNP) | VAF 32/286 reads (11%) | catalogued as rs141236185, COSV51889003, COSV99233418; called by mutect2, varscan2
- ZSCAN10 | c.597T>C p.N199= (on ENST00000252463; = p.N254= on NM_032805.3) | Silent (SNP) | VAF 40/295 reads (14%) | called by mutect2, varscan2
- ASIC1 | c.1297+68A>G | Intron (SNP) | VAF 50/342 reads (15%) | called by mutect2, varscan2
- CFLAR | c.1305-790T>C | Intron (SNP) | VAF 34/262 reads (13%) | called by mutect2, varscan2
- DMWD | c.*497A>C | 3'UTR (SNP) | VAF 44/326 reads (13%) | called by mutect2, varscan2
- XIRP2 | c.*334A>G | 3'UTR (SNP) | VAF 54/384 reads (14%) | called by mutect2, varscan2
- ZNF559 | c.244-237A>C | Intron (SNP) | VAF 28/168 reads (17%) | called by mutect2, varscan2
